Somatic mutation profile of tumor specimen MP2PRT-PASRXA-TMP1-A (aliquot MP2PRT-PASRXA-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASRXA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,096 days).
Specimen MP2PRT-PASRXA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fbebe495-d451-4ee6-a07d-84f595259b66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRXA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRXA-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c3a097c-dbbb-42d9-8ae0-a6cc2eefb6ba

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 33/384 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AP000311.1 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 24/429 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs150994121, COSV51708753; called by muse, mutect2
- ITGA3 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 71/252 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs566143997; called by muse, mutect2, varscan2
- KRTAP10-3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 36/1058 reads (3%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs372171182; called by muse, mutect2
- PDZD2 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1359512397, COSV56854459; called by muse, mutect2, varscan2
- SMARCA4 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60787768; called by muse, mutect2
- DEPDC1 | c.174A>T p.R58S | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- FAM155A | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- JSRP1 | c.987G>A p.G329= | Silent (SNP) | VAF 48/304 reads (16%) | called by muse, mutect2, varscan2
- KCND3 | c.453C>T p.N151= | Silent (SNP) | VAF 39/345 reads (11%) | catalogued as rs778897221, COSV56179078; called by muse, mutect2, varscan2
- POU2F3 | c.402C>T p.S134= | Silent (SNP) | VAF 34/430 reads (8%) | catalogued as rs367755083, COSV99501475; called by muse, mutect2
- SMCP | c.333G>A p.E111= | Silent (SNP) | VAF 41/324 reads (13%) | called by muse, mutect2, varscan2
